Somatic mutation profile of tumor specimen TCGA-KK-A6E4-01A (aliquot TCGA-KK-A6E4-01A-11D-A30E-08) from TCGA case TCGA-KK-A6E4, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.4 years (25,338 days).
Specimen TCGA-KK-A6E4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a098d498-bf55-4411-895e-823bbff9dc7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E4-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E4-11A-11D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6504cb1-39be-49b6-b737-ce72f8917e28

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 22, Silent 13, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARNT2 | c.1836del p.Y613Tfs*214 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | catalogued as COSV57587049; called by mutect2, pindel, varscan2
- BBS10 | c.791T>G p.I264S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1236502453, COSV53886662; called by muse, mutect2, varscan2
- BCAR3 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV53073814; called by muse, mutect2
- CACNA1D | c.4709A>G p.N1570S (on ENST00000350061 / NM_001128840.3; = p.N1590S on NM_000720.4) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs778718562, COSV99856847; called by muse, mutect2, varscan2
- CCND3 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV65913019; called by muse, mutect2, varscan2
- CDHR1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as rs184579670, COSV60564695; called by muse, mutect2, varscan2
- CFAP206 | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as rs1237606656, COSV65808629; called by muse, mutect2, varscan2
- CSPP1 | c.3449G>A p.R1150H (on ENST00000676605; = p.R1109H on NM_024790.6) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs775362535, COSV51588797; called by muse, mutect2, varscan2
- EXTL3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV55039186; called by muse, mutect2, varscan2
- EYS | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs377622148, COSV100675758; called by muse, mutect2, varscan2
- GNAI1 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV63524175; called by muse, mutect2, varscan2
- GNB1L | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.264); catalogued as rs777605606, COSV61549138; called by muse, mutect2, varscan2
- MYO15A | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs934249137, COSV52761349; called by muse, mutect2, varscan2
- OR5AS1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs370300707; called by muse, mutect2, varscan2
- PI4KA | c.4409G>T p.G1470V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV55417297; called by muse, varscan2
- PLAA | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs759709062, COSV68305310; called by muse, mutect2, varscan2
- PTCH2 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1050285039, COSV64710001; called by muse, mutect2, varscan2
- RAD21 | c.932T>A p.I311K | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV52061629; called by muse, mutect2, varscan2
- SOS1 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV67676629; called by muse, mutect2, varscan2
- SPIB | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54531955; called by muse, mutect2, varscan2
- SYNE3 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs753892119, COSV62080994; called by muse, mutect2, varscan2
- TTN | c.101954T>G p.L33985* (on ENST00000591111; = p.L26561* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV60210267; called by muse, mutect2, varscan2
- WDR11 | c.2767G>T p.E923* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54790709; called by muse, mutect2, varscan2
- ZNF804B | c.2680G>A p.G894R | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs377052292, COSV60826143, COSV60829416; called by muse, mutect2, varscan2
- ZSWIM8 | c.3905G>A p.R1302H (on ENST00000605216 / NM_001242487.2; = p.R1307H on NM_015037.3) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1284563534, COSV100013736; called by muse, mutect2
- AADACL4 | c.1131C>T p.H377= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs368235693; called by muse, mutect2, varscan2
- ABTB1 | c.1260G>A p.A420= (on ENST00000232744 / NM_172027.3; = p.A278= on NM_032548.3) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs780489088, COSV51740144; called by muse, mutect2, varscan2
- ATP1A2 | c.1359T>C p.A453= | Silent (SNP) | VAF 29/263 reads (11%) | catalogued as COSV63404963; called by muse, mutect2, varscan2
- EXTL3 | c.210G>A p.G70= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV55039193; called by muse, mutect2, varscan2
- GEMIN5 | c.4077C>G p.L1359= | Silent (SNP) | VAF 10/185 reads (5%) | catalogued as COSV53562495, COSV53562890; called by muse, mutect2
- HOXD12 | c.534G>A p.A178= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV66832804; called by muse, mutect2, varscan2
- OR4K5 | c.933T>A p.I311= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV60004401; called by muse, mutect2, varscan2
- PCDHA9 | c.1443C>T p.D481= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV65329757; called by muse, mutect2, varscan2
- RSPH10B2 | c.540C>T p.I180= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs760981104, COSV99785993; called by mutect2, varscan2
- SPECC1L | c.738G>A p.L246= | Silent (SNP) | VAF 41/192 reads (21%) | catalogued as COSV58660145; called by muse, mutect2, varscan2
- SPTA1 | c.3702C>A p.P1234= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as rs376004665, COSV63752058; called by muse, mutect2, varscan2
- SYTL5 | c.738G>A p.R246= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99936941; called by muse, mutect2
- WDFY3 | c.4416C>T p.I1472= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs146868524; called by muse, mutect2, varscan2
